Gene-level copy-number profile of tumor specimen TCGA-CV-7430-01A from TCGA case TCGA-CV-7430, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 56.8 years (20,763 days).
Specimen TCGA-CV-7430-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.a2c197d5-2c50-49a5-9430-266f02e233f4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CV-7430-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1e26ffc8-00e8-4d6f-a681-68c68d29da3e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 227; copy number 1: 15,684; copy number 2: 37,238; copy number 3: 5,133; copy number 4: 366; copy number 5: 23; copy number 6: 73; copy number 8: 1,064; copy number 9: 2; copy number 10: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CV-7430-01A-11D-2128-01): tumor purity 0.76, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 227 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:20,386,386–20,401,724, 2 genes: SLC7A15P, RNA5SP86.
- chr7:23,490,473–24,694,193, 21 genes (within-gene range 0–1): RPS2P32, Y_RNA, TRA2A, AC006026.1, CLK2P1, CCDC126, FCF1P1, AC006026.2, FAM221A, AC006026.3, STK31, PCMTD1P3, TPT1P7, AC003087.1, RNA5SP228, AC004485.1, NPY, AC003044.1, RNU6-1103P, MPP6, SUMO2P14.
- chr8:3,373,353–3,700,628, 3 genes: AC026991.1, AC026991.2, RNA5SP251.
- chr9:20,999,509–24,088,051, 71 genes (broad region; genes not listed).
- chr19:55,836,540–58,054,631, 130 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,165 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–2,089,211, 21 genes, copy number 5: LINC01986, AC066595.1, CHL1-AS2, AC066595.2, CHL1, RNU6-1194P, RPS8P6, CHL1-AS1, AC087428.1, LINC01266, RPSAP32, AC090044.1, AC087430.1, RN7SL120P, CNTN6, CRB3P1, RPL23AP38, RPL23AP39, RPL21P17, AC018814.1, RN7SKP144.
- chr3:2,110,409–2,144,241, 2 genes, copy number 5: CNTN4-AS2, AC087427.1.
- chr3:6,490,460–9,363,053, 27 genes, copy number 8 (within-gene range 1–8): AC069277.1, GRM7-AS3, AC069277.2, GRM7, MRPS36P1, GRM7-AS2, AC066585.1, GRM7-AS1, AC077690.1, LMCD1-AS1, AC018832.1, AC023481.1, RNU4ATAC17P, LMCD1, AC034187.1, SSUH2, OR7E122P, CAV3, OXTR, RAD18, AC034186.2, AC034186.1, SRGAP3, SRGAP3-AS1, AC037193.1, SRGAP3-AS2, SRGAP3-AS3.
- chr3:138,935,189–198,222,513, 1,037 genes, copy number 8 (broad region; genes not listed).
- chr4:65,702,202–65,860,204, 3 genes, copy number 10: AC104137.1, RNU2-40P, AC097110.1.
- chr4:86,823,468–89,999,409, 75 genes, copy number 6–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 13,263. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
